Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XB, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XB-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer in the upper outer quadrant sucking skin

ICD-0-3

Carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9 for 4/12/11

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive carcinoma cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

Right breast sized 18 x 12.5 x 3 cm removed along with axillary tissues sized 10 x 6 x 2 cm, a skin flap of 16.5 x 5.3 cm, and a piece of the muscle sized 1 x 1 x 0.4 cm.

Tumour sized 2.1 x 1 x 1.5 cm found in upper outer quadrant, located 1.5 cm from the upper boundary, 0.2 cm from the base and 0 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum – NHG1 (2+2+1/10 mitoses/10 HPF - visual area 0.55mm). Foci of carcinoma ductale in situ (DCIS) found within the tumour (cribrate type, with medium nuclear atypia, without necrosis, with calcifications covering 5% of the tumour). Calcificationes in tumore. Mamilla sine laesionibus.

Glandular tissue showing lesions of the type mastopathia fibrosa, microcalcificationes, fibroadenoma.

AXILLARY LYMPH NODES: Metastases in lymphonodo (NO I/X).

Infiltratio capsulae lymphonodo et telae perinodalis

Histopathological diagnosis:

Carcinoma ductale invasivum et ductale in situ mammae dextrae. Metastases lymphonodo axillae (No I/X). (NHG1, pT2, pN1a). Invasive ductal carcinoma and ductal carcinoma in situ of the right breast. Cancer metastases in axillary lymph nodes (No I/X). (NHG1, pT2, pN1a).

Compliance validated by:

Examination performed on:

Case in Court		X
Review by Tumor Board		X

for 4/12/11

Source: NCI Genomic Data Commons file 4b5498c0-90e7-491c-ba44-7c55ed3736e8 (TCGA-D8-A1XB.B7367E27-2A40-4E8F-8975-D5665E6506D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).